Somatic mutation profile of tumor specimen MP2PRT-PANWMS-TBP1-A (aliquot MP2PRT-PANWMS-TBP1-A-1-0-D-A82K-36) from MP2PRT case MP2PRT-PANWMS, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphoblastic leukemia, NOS; Tissue or organ of origin: Blood; Age at diagnosis: 3.7 years (1,353 days).
Specimen MP2PRT-PANWMS-TBP1-A: Sample type: Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Biospecimen anatomic site: Blood; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) eaa9f8ec-a8fd-4a84-9094-1b63eda66de9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PANWMS-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PANWMS-NB1-A-1-0-D-A82K-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d5001532-fccd-4c71-801a-640f01581320

The open-access MAF lists 13 somatic variants for this specimen: 9 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 7, Silent 4, In Frame Del 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FAM83B | c.617G>A p.R206Q | Missense Mutation (SNP) | VAF 38/202 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs757944460, COSV60919217; called by muse, varscan2
- NRG1 | c.109C>T p.R37C (on ENST00000523534; = p.R184C on NM_013962.2) | Missense Mutation (SNP) | VAF 169/550 reads (31%) | SIFT tolerated, low confidence (0.1); PolyPhen probably damaging (0.992); catalogued as rs771177404, COSV101584745; called by muse, varscan2
- P2RY1 | c.667G>A p.V223M | Missense Mutation (SNP) | VAF 109/447 reads (24%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.979); catalogued as rs374496347; called by muse, mutect2, varscan2
- TRPC7 | c.652C>T p.R218C | Missense Mutation (SNP) | VAF 38/540 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1192422925, COSV100725798; called by muse, mutect2
- COL21A1 | c.1534G>A p.G512S | Missense Mutation (SNP) | VAF 86/420 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- COL6A3 | c.6411T>C p.G2137= | Splice Region (SNP) | VAF 25/348 reads (7%) | called by muse, mutect2
- IL11 | c.482T>C p.L161P | Missense Mutation (SNP) | VAF 38/678 reads (6%) | SIFT tolerated (0.13); PolyPhen benign (0.013); called by muse, mutect2
- STK40 | c.533_535del p.F178del | In Frame Del (DEL) | VAF 68/314 reads (22%) | called by pindel, varscan2
- TMC2 | c.176G>A p.R59H | Missense Mutation (SNP) | VAF 24/716 reads (3%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.045); called by muse, mutect2
- DLGAP1 | c.798G>A p.P266= | Silent (SNP) | VAF 145/672 reads (22%) | catalogued as rs763989171; called by muse, mutect2, varscan2
- GLI3 | c.4341C>T p.T1447= | Silent (SNP) | VAF 42/540 reads (8%) | catalogued as rs956536432; called by muse, mutect2
- RBMXL3 | c.1989C>T p.Y663= | Silent (SNP) | VAF 40/1101 reads (4%) | catalogued as rs1209297902; called by muse, mutect2
- SORCS2 | c.789C>T p.V263= | Silent (SNP) | VAF 69/346 reads (20%) | called by muse, mutect2, varscan2
